Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-4682, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-4682-01B (Primary Tumor).

FINAL DIAGNOSIS:

PARTS 1,

2 AND 3: SIGMOID COLON, COLECTOMY -

- A. INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA (3.0 CM) THROUGH MUSCULARIS PROPRIA INTO PERIRECTAL FAT.
- B. NO ANGIOLYMPHATIC INVASION IDENTIFIED.
- C. SURGICAL RESECTION MARGINS FREE OF TUMOR.
- D. THREE PERICOLONIC LYMPH NODES, FREE OF TUMOR (0/3).
- E. PATHOLOGIC STAGE pT3 N0 M1.
- F. HYPERPLASTIC POLYPS.

PART 4: LIVER, BIOPSY -

METASTATIC MODERATELY DIFFERENTIATED ADENOCARCINOMA (see comment)

MICROSCOPIC:

SYNOPTIC DATA - PRIMARY COLON AND RECTAL TUMORS

SPECIMEN TYPE:	Rectal/rectosigmoid colon (low anterior resection)
SPECIMEN LENGTH:	32.0 cm
TUMOR SITE:	Rectosigmoid
TUMOR CONFIGURATION:	Ulcerating
TUMOR SIZE:	Greatest dimension: 3.0 cm
INTACTNESS OF MESORECTUM:	Not applicable
HISTOLOGIC TYPE:	Adenocarcinoma
HISTOLOGIC GRADE:	Low-grade (well to moderately differentiated)
PATHOLOGIC STAGING (pTNM):	pT3
	pN0
	Number of nodes examined: 3
	Number of nodes involved: 0
	pM1
MARGINS:	Proximal margin uninvolved by invasive carcinoma
	Distal margin uninvolved by invasive carcinoma
	Circumferential (radial) margin uninvolved by invasive carcinoma
	Mesenteric margin cannot be assessed
ANGIOLYMPHATIC INVASION:	Absent
PERINEURAL INVASION:	Absent
TUMORAL LYMPHOCYTIC RESPONSE:	Mild to moderate
ADDITIONAL PATHOLOGIC FINDINGS:	Other polyps (type[s]): Hyperplastic polyps

Source: NCI Genomic Data Commons file 0138414a-aa54-4ad7-813a-c01fae2abec9 (TCGA-AZ-4682.DBBCD290-F43A-4494-9914-D490DFC24D84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).